Somatic mutation profile of tumor specimen MMRF_1250_1_BM_CD138pos (aliquot MMRF_1250_1_BM_CD138pos_T2_KAS5U_L02451) from MMRF case MMRF_1250, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.2 years (21,614 days).
Specimen MMRF_1250_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2708ac33-108b-4752-b2b3-431bd4332ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1250_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1250_1_PB_Whole_C3_KAS5U_L02462; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6292572c-3070-4daf-af9b-3748ff4d58f5

The open-access MAF lists 75 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 18, Intron 13, Silent 5, Nonsense Mutation 3, In Frame Del 3, 3'Flank 2, Nonstop Mutation 1, Splice Site 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs193009561, COSV100933396; called by muse, mutect2, varscan2
- COIL | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53594373; called by muse, mutect2, varscan2
- GSTA1 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1203988377; called by muse, mutect2, varscan2
- GUCA1C | c.628T>C p.*210Qext*2 | Nonstop Mutation (SNP) | VAF 62/185 reads (34%) | catalogued as rs1020871668; called by muse, mutect2, varscan2
- IGLV2-14 | c.135C>G p.S45R | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as rs11539994; called by muse, varscan2
- KCNMA1 | c.31_51del p.S11_G17del | In Frame Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs1484259264; ClinVar: uncertain significance; called by mutect2, varscan2
- LRP1B | c.13273C>T p.Q4425* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs767972971, COSV67249302; called by muse, mutect2, varscan2
- MUC16 | c.36669G>A p.T12223= | Splice Region (SNP) | VAF 50/69 reads (72%) | catalogued as rs547301792, COSV101198853; called by muse, mutect2, varscan2
- NFKBIA | c.888_896del p.F298_E300del | In Frame Del (DEL) | VAF 33/130 reads (25%) | catalogued as rs1428421661; called by mutect2, varscan2
- SLC3A2 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs979740918, COSV58604430; called by muse, mutect2, varscan2
- SV2B | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 62/125 reads (50%) | catalogued as rs767247777, COSV57700498; called by muse, mutect2, varscan2
- TNC | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs779621288, COSV60780573; called by muse, mutect2, varscan2
- ARSG | c.160A>C p.N54H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- ELAVL2 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 258/366 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ELN | c.2251G>A p.A751T (on ENST00000320399 / NM_001278939.1; = p.A718T on NM_000501.4) | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM9B | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 61/65 reads (94%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- HIVEP1 | c.7001C>G p.P2334R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- IGHV2-70D | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, varscan2
- KIF12 | c.550C>T p.P184S (on ENST00000640217; = p.P46S on NM_138424.1) | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- NPBWR1 | c.-198+2T>G | Splice Site (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- OCA2 | c.790T>C p.W264R | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRT2 | c.225_226insTG p.A76Wfs*15 | Frame Shift Ins (INS) | VAF 36/95 reads (38%) | called by mutect2, pindel, varscan2
- RAB35 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.156); called by muse, mutect2
- RGSL1 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX25 | c.2381_2389del p.H794_I797delinsL | In Frame Del (DEL) | VAF 39/85 reads (46%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.5144C>T p.A1715V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- STYK1 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- TMTC3 | c.440del p.L147Cfs*7 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- TRIM71 | c.2334C>A p.C778* | Nonsense Mutation (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- FCN2 | c.939C>T p.A313= | Silent (SNP) | VAF 56/168 reads (33%) | called by muse, mutect2, varscan2
- GNAI1 | c.285T>C p.F95= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs539499460; called by muse, mutect2, varscan2
- HMCN2 | c.5376C>T p.T1792= | Silent (SNP) | VAF 38/48 reads (79%) | called by muse, mutect2, varscan2
- SLC22A12 | c.636C>T p.G212= | Silent (SNP) | VAF 126/203 reads (62%) | catalogued as rs1272829728, COSV60572238; called by muse, mutect2, varscan2
- UBE3A | c.150G>A p.T50= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as rs760283316, COSV99217323; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM28 | c.1567+207_1567+213del | Intron (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.*109T>C | 3'UTR (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.*1741_*1743del | 3'UTR (DEL) | VAF 5/56 reads (9%) | catalogued as rs1299637360; called by pindel, varscan2*
- ATP10A | c.449+574G>A | Intron (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- BMP6 | c.*140A>G | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- BMP6 | c.*390_*394delinsG | 3'UTR (DEL) | VAF 38/149 reads (26%) | called by pindel, varscan2*
- BMPR2 | c.*3081_*3083del | 3'UTR (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- CACNB4 | c.*5655C>T | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- CCNC | c.*213T>G | 3'UTR (SNP) | VAF 57/86 reads (66%) | called by muse, mutect2, varscan2
- CCNC | c.346+38T>C | Intron (SNP) | VAF 168/260 reads (65%) | called by muse, mutect2, varscan2
- COPS7B | c.*1316del | 3'UTR (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- CTBP2 | c.58+12057G>A | Intron (SNP) | VAF 48/119 reads (40%) | catalogued as rs374532569; called by muse, mutect2, varscan2
- CX3CR1 | c.*207A>G | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- EYS | c.7724-57_7724-55del | Intron (DEL) | VAF 102/201 reads (51%) | catalogued as rs926959867; called by pindel, varscan2
- GIMAP1 | c.*1351C>T | 3'UTR (SNP) | VAF 38/100 reads (38%) | catalogued as rs981868502; called by muse, mutect2, varscan2
- HRH2 | chr5:175686049 G>A | 3'Flank (SNP) | VAF 98/200 reads (49%) | called by muse, mutect2, varscan2
- ICE2 | c.*57G>A | 3'UTR (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
- KIFC3 | c.2476+97del | Intron (DEL) | VAF 52/102 reads (51%) | called by mutect2, pindel, varscan2
- LINC02253 | n.575-1188T>G | Intron (SNP) | VAF 176/333 reads (53%) | called by muse, mutect2, varscan2
- LTB | c.163-63C>T | Intron (SNP) | VAF 122/416 reads (29%) | catalogued as COSV53002669; called by muse, mutect2, varscan2
- LYPD6 | c.*1936G>A | 3'UTR (SNP) | VAF 21/38 reads (55%) | catalogued as rs368371941; called by muse, mutect2, varscan2
- LYVE1 | c.*1582C>T | 3'UTR (SNP) | VAF 39/60 reads (65%) | catalogued as rs1383180135; called by muse, mutect2, varscan2
- NEMP1 | c.*1166T>C | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- OPRL1 | c.*253G>T | 3'UTR (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248453893 G>A | 3'Flank (SNP) | VAF 57/186 reads (31%) | catalogued as rs1202067702; called by muse, mutect2, varscan2
- PCDH19 | c.*3477A>T | 3'UTR (SNP) | VAF 24/27 reads (89%) | called by muse, mutect2, varscan2
- PDE6A | c.*1087C>T | 3'UTR (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- PGAP4 | c.*547C>A | 3'UTR (SNP) | VAF 62/92 reads (67%) | called by muse, mutect2, varscan2
- PRRG4 | c.*475T>C | 3'UTR (SNP) | VAF 37/111 reads (33%) | catalogued as rs913081296; called by muse, mutect2, varscan2
- PSD3 | c.1910+114A>G | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- RAB30 | c.361+505T>A | Intron (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- RFC4 | c.882+13T>C | Intron (SNP) | VAF 81/209 reads (39%) | called by muse, mutect2, varscan2
- SCARA5 | c.1154-6281_1154-6279del | Intron (DEL) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- SPRR4 | c.*151C>A | 3'UTR (SNP) | VAF 53/139 reads (38%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.-377T>C | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- TRMT61A | c.*2144T>C | 3'UTR (SNP) | VAF 57/198 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.10360+2200G>A | Intron (SNP) | VAF 21/52 reads (40%) | catalogued as rs1295483163, COSV100591122; called by muse, mutect2, varscan2
- WT1 | c.*1049del | 3'UTR (DEL) | VAF 5/40 reads (13%) | catalogued as rs568803808, COSV60072460; ClinVar: benign; called by pindel, varscan2
- YWHAQ | c.*584G>A | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- ZADH2 | c.*5593T>A | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- ZNF468 | c.*65T>C | 3'UTR (SNP) | VAF 186/293 reads (63%) | called by muse, mutect2, varscan2
